CCDI case PBBNII — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Testis.
https://portal.gdc.cancer.gov/cases/88562abf-c336-4be6-b077-3951c82bd15d

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Genital rhabdomyoma: ICD-O-3 morphology code: 8905/0; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 15.0 years (5,489 days).

Biospecimens (3 samples)
- Sample 0DD86Y: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DD86Z: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DD874: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
